Surgical pathology report (de-identified scan), TCGA case TCGA-KT-A74X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Hartford, specimen TCGA-KT-A74X-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

#1, #2, #3 BRAIN, LEFT TEMPORAL-PARIETAL, RESECTION:

FOCI OF "ANAPLASTIC MIXED GLIOMA" IN A BACKGROUND OF PREDOMINANTLY GRADE II OLIGODENDROGLIOMA. SEE COMMENT.

Electronically Signed Out

COMMENT

Sections show a diffusely infiltrating glioma predominantly oligodendroglioma with uniform, round nuclei, perinuclear halos and thin-walled capillaries in a chicken wire pattern. There are identifiable mitoses, up to 4/10 HPF in the oligodendroglioma areas (slide 3C) and focally vascular endothelial proliferation. Several sections (in particular 2A) show astrocytoma component with mitotic activity (more than 2 mitotic figures).

Immunohistochemical stain results of GFAP shows variable positivity, IDH1 is positive and MIB-1 shows overall average labeling of approximately 5%.

Molecular testing for 1p19q status was performed and is positive for co-deletion. See separate molecular pathology report.

88307, 88342x3, 88331

Clinical Diagnosis and History:

Brain tumor (left temporal / parietal)

Tissue(s) Submitted:

- 1: BRAIN TUMOR
- 2: ADDITIONAL BRAIN TUMOR
- 3: ADDITIONAL BRAIN TUMOR

Gross Description:

Specimen #1 is received fresh for frozen section and labeled as brain tumor and consists of several fragments of a brain measuring 4.0 x 3.0 x 2.0 cm in aggregate. Part of the specimen is submitted for frozen section and the remainder for microscopic examination.

Summary of Sections:

- 1AFS: frozen section tissue
- 1B-1D: remainder of the specimen submitted for microscopic examination.

CSCE ICD O-3
Oligodendroglioma, grade II
path 9382/3
gloma mixed anaplastic
CSCE 9382/3
Site 4 Brain, supratentorial NOS
path C71.0
Overlapping lesion of brain C71.8

[page 2 of 3]
Surgical Pathology Report

Specimen #2 is received fresh for frozen section and labeled as additional brain tumor and consists of several fragments of brain measuring 8.0 x 4.0 x 0.6 cm in aggregate. Part of the specimen is submitted for frozen section and the remainder for microscopic examination.

Summary of Sections:

2AFS: remainder of the frozen section tissue

2B-2G: entire specimen.

Specimen #3 is received fresh for microscopic examination and labeled as additional brain tumor and consists of a fragment of brain measuring 7.0 x 8.0 x 2.0 cm. The specimen is serially sectioned showing effacement of the white and gray matter with small patchy areas of necrosis. Representative sections are submitted for microscopic examination.

Summary of Sections:

3A-3C: representative sections.

3D-3S: additional sections.

Intraoperative Consult Diagnosis

1A/ FSDX: LOW GRADE GLIOMA? ASTROCYTOMA? OLIGO COMPONENT, DEFER TO PERMANENT.

Procedures/Addenda

FISH, 1p/19q

Fluorescence In Situ Hybridization (FISH) Study Paraffin Embedded Tissue Left Temporal/Parietal Brain Tumor 1p36/ 1q25 and 19q13/ 19p13

FISH Probes: 1p36 1q25 and 19q13 19p13 Nuclei Scored: 50

Result: POSITIVE FOR 1p GENE DELETION

Total # signals/total # nuclei counted for 1p probe = 62

Total # signals/total # nuclei counted for 1q probe = 90

1p/1q = 0.69

POSITIVE FOR 19q GENE DELETION

Total # signals/total # nuclei counted for 19q probe = 60

Total # signals/total # nuclei counted for 19p probe = 97

19q/19p = 0.62

Background: The most prevalent genetic anomaly in both grade II and grade III oligodendrogliomas is co-deletion of chromosome arms 1p and 19q¹. It was recently shown that the co-deletion of 1p and 19q is mediated by an unbalanced translocation t(1;19)(q10;p10)². Loss of 1p and 19q has been used as a diagnostic as well as prognostic marker of oligodendroglial tumors. Recent literature^{2,3} suggests that oligodendrogliomas with loss of 1p and 19q are likely more responsive to chemotherapeutic drugs/ radiation therapy, and such tumors may represent a "favorable" form of oligodendrogliomas.

Method: The 1p36/ 1q25 and 19q / 19p13 were applied to the provided paraffin-embedded tissue sections. This probe set contains 1p36 and 1q25 in one vial. The other set/vial contains 19q13 and 19p13. The probe sets were applied individually to treated tissue sections and then sections were viewed and interphase nuclei were examined for corresponding signals.

[page 3 of 3]
Surgical Pathology Report

Disclaimer: This test was developed and its performance characteristics determined by the Administration. FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

References:

1. van den Bent MJ (2000): Chemotherapy of oligodendroglial tumours: current developments. Forum 10:108-118.
2. Jenkens, RB, Blair H, Ballman, KV et al. (2006) A t(1;19)(q10;p10) mediates the combined deletions of 1p and 19q and predicts a better prognosis of patients with oligodendrogliomas. Cancer Res 66:9852-9861.
3. Caincross G, Seiferheld W, Shaw EG, et al. An intergroup randomized controlled clinical trial (RCT) of chemotherapy plus radiotherapy versus RT alone for pure and mixed anaplastic oligodendroglioma: initial report of RTOG 94-02. Neuro-oncol 2004;6:371.
- Clinical Diagnosis and History: Brain tumor*

Laboratory results and interpretation reviewed by:

[REDACTED]
[REDACTED]
[REDACTED]

For internal laboratory use only:

END OF REPORT

Source: NCI Genomic Data Commons file 08309191-cd5a-4c9d-bca4-a182ecd7cdf8 (TCGA-KT-A74X.70559888-99AB-44B6-8553-AF8EF504268A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).